Somatic mutation profile of tumor specimen TCGA-2Z-A9J1-01A (aliquot TCGA-2Z-A9J1-01A-11D-A382-10) from TCGA case TCGA-2Z-A9J1, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 71.9 years (26,244 days).
Specimen TCGA-2Z-A9J1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e0c02d3-c1b7-4438-beec-676ad38e8144.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Z-A9J1-10A (Blood Derived Normal), aliquot TCGA-2Z-A9J1-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d776f0e7-027a-4200-8130-ed61e2a49910

The open-access MAF lists 100 somatic variants for this specimen: 77 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 58, Silent 23, Frame Shift Del 9, Nonsense Mutation 3, Frame Shift Ins 2, Splice Region 2, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADM | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.653); catalogued as CD054289, COSV100897750, COSV63720894; called by muse, mutect2, varscan2
- ADAM19 | c.2518A>C p.I840L | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99978244; called by muse, mutect2, varscan2
- ANKRD50 | c.3361C>A p.L1121I | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV101539031; called by muse, mutect2, varscan2
- APOD | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as COSV100581281; called by muse, mutect2, varscan2
- ARHGEF10 | c.3338C>G p.S1113C (on ENST00000398564; = p.S1088C on NM_014629.4) | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100035455, COSV50646064; called by muse, mutect2, varscan2
- ARRDC3 | c.1133C>A p.P378Q | Missense Mutation (SNP) | VAF 62/228 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as COSV99475379; called by muse, mutect2, varscan2
- ATP2B3 | c.2894C>A p.P965H | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99685596; called by muse, mutect2, varscan2
- C6 | c.371T>A p.F124Y | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as COSV99667666; called by muse, mutect2, varscan2
- CALU | c.568G>C p.D190H | Missense Mutation (SNP) | VAF 81/254 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99975879; called by muse, mutect2, varscan2
- CDON | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.424); catalogued as COSV99701884; called by muse, mutect2, varscan2
- CLEC1A | c.780G>C p.R260S | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100191692; called by muse, mutect2, varscan2
- CNTRL | c.2138A>G p.N713S | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99443527; called by muse, mutect2, varscan2
- CPNE5 | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329142279, COSV99783234; called by muse, mutect2, varscan2
- CROCC | c.2786A>T p.Q929L | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV100978379; called by muse, mutect2, varscan2
- CSNK1E | c.751T>A p.Y251N | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100725086; called by muse, mutect2, varscan2
- DDX11 | c.2532G>C p.R844S (on ENST00000545668 / NM_152438.2; = p.G796A on NM_004399.3) | Missense Mutation (SNP) | VAF 74/142 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); catalogued as COSV99300149; called by muse, mutect2
- DLC1 | c.1259C>G p.T420R | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.144); catalogued as COSV52317683, COSV99365075; called by muse, mutect2, varscan2
- ESR2 | c.1479G>T p.E493D | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV99963756; called by muse, mutect2, varscan2
- FKBP8 | c.68A>T p.D23V | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV99724250; called by muse, mutect2, varscan2
- GJD3 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100492291; called by muse, mutect2, varscan2
- GPSM1 | c.1144C>A p.L382I | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV100696675; called by muse, mutect2, varscan2
- GUCA2A | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV100813034, COSV63691489; called by muse, mutect2, varscan2
- IGF2R | c.999G>T p.E333D | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100808053; called by muse, mutect2, varscan2
- ITIH2 | c.1647G>T p.S549= | Splice Region (SNP) | VAF 26/79 reads (33%) | catalogued as COSV100623389, COSV64431761; called by muse, mutect2, varscan2
- KCNB1 | c.873T>A p.N291K | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100870358, COSV100870578; called by muse, mutect2, varscan2
- LMO7 | c.1502T>G p.F501C (on ENST00000357063; = p.F231C on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1374776726, COSV100413807, COSV100413808; called by muse, mutect2, varscan2
- LRWD1 | c.812T>A p.V271E | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV99479526; called by muse, mutect2, varscan2
- MAP1B | c.1391C>G p.S464C | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV57101905, COSV99702876; called by muse, mutect2, varscan2
- MGA | c.1750G>C p.G584R | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99581281; called by muse, mutect2, varscan2
- MRPS10 | c.270T>A p.S90R | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99273650; called by muse, mutect2, varscan2
- MYO1H | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV100183916; called by muse, mutect2, varscan2
- NBEA | c.8074A>G p.I2692V | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as rs762819158, COSV100083473, COSV59807219; called by muse, mutect2, varscan2
- NBPF1 | c.1406A>G p.K469R | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV99844850; called by muse, mutect2, varscan2
- NCF2 | c.386T>A p.F129Y | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV100838940; called by muse, mutect2, varscan2
- NFIC | c.1082G>T p.S361I | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100545614; called by muse, mutect2, varscan2
- NME8 | c.995A>T p.D332V | Missense Mutation (SNP) | VAF 66/311 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs764183917, COSV99553763; called by muse, mutect2, varscan2
- NUP205 | c.4072T>G p.S1358A | Missense Mutation (SNP) | VAF 63/119 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99607472; called by muse, mutect2, varscan2
- NUP210L | c.1966G>C p.A656P | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV99668875; called by muse, mutect2, varscan2
- OBI1 | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99932596; called by muse, mutect2
- P2RY8 | c.704C>G p.A235G | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV101184172, COSV67176674; called by muse, mutect2, varscan2
- PAWR | c.901G>C p.G301R | Missense Mutation (SNP) | VAF 65/120 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as COSV100174377; called by muse, mutect2, varscan2
- PCSK6 | c.1764del p.F588Lfs*2 | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | catalogued as COSV100083012; called by mutect2, pindel, varscan2
- PCYT2 | c.481C>A p.H161N | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.67); catalogued as COSV100155703; called by muse, mutect2, varscan2
- PDE4DIP | c.1430T>A p.L477H | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100521342; called by muse, mutect2, varscan2
- PUM2 | c.2136A>T p.E712D | Missense Mutation (SNP) | VAF 69/110 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.137); catalogued as COSV100163931; called by muse, mutect2, varscan2
- PWWP3A | c.1924G>A p.A642T (on ENST00000627377; = p.A641T on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.219); catalogued as rs1168721240, COSV100262236; called by muse, mutect2, varscan2
- RAVER2 | c.1477A>C p.N493H (on ENST00000294428 / NM_001366165.1; = p.N480H on NM_018211.4) | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV99605581; called by muse, mutect2, varscan2
- RIMBP2 | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs768672690, COSV55472070, COSV99900290; called by muse, mutect2, varscan2
- RIPK1 | c.935A>G p.N312S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1335621385, COSV99454832; called by muse, mutect2, varscan2
- SAMD9 | c.2814T>A p.C938* | Nonsense Mutation (SNP) | VAF 61/119 reads (51%) | catalogued as COSV101180350; called by muse, mutect2, varscan2
- SCAP | c.190T>A p.Y64N | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV99653190; called by muse, mutect2, varscan2
- SEL1L3 | c.2275T>A p.S759T | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV99341116; called by muse, mutect2, varscan2
- SF3A3 | c.1022C>G p.T341S | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs767329284, COSV100885685; called by muse, mutect2, varscan2
- SGTB | c.373A>T p.R125W | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101121616; called by muse, mutect2, varscan2
- SHH | c.1033T>C p.Y345H | Missense Mutation (SNP) | VAF 215/887 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99793529; called by muse, mutect2, varscan2
- SLC5A5 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs1426316490, COSV99715327; called by muse, mutect2
- SLC8A1 | c.2198C>A p.T733K | Missense Mutation (SNP) | VAF 80/101 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV100247239; called by muse, mutect2, varscan2
- STRN4 | c.1596C>T p.D532= | Splice Region (SNP) | VAF 13/53 reads (25%) | catalogued as rs1406866123, COSV99623979; called by muse, mutect2, varscan2
- SYPL1 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs773229281, COSV99163464; called by muse, mutect2, varscan2
- TMEM87B | c.1418T>A p.I473N | Missense Mutation (SNP) | VAF 146/204 reads (72%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99314609; called by muse, mutect2, varscan2
- TNKS2 | c.1326T>A p.Y442* | Nonsense Mutation (SNP) | VAF 41/107 reads (38%) | catalogued as COSV100861153; called by muse, mutect2, varscan2
- TULP4 | c.1821A>C p.K607N | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100893784, COSV65580764; called by muse, mutect2, varscan2
- XKRX | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 143/185 reads (77%) | SIFT tolerated (0.62); PolyPhen benign (0.096); catalogued as rs746964281, COSV100139796; called by muse, mutect2, varscan2
- ZNF831 | c.4561G>C p.G1521R | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100926217; called by muse, mutect2
- AAAS | c.1390_1392del p.F464del | In Frame Del (DEL) | VAF 57/123 reads (46%) | called by mutect2, pindel, varscan2
- CLCN3 | c.900del p.P301Qfs*24 | Frame Shift Del (DEL) | VAF 63/219 reads (29%) | called by mutect2, pindel, varscan2
- DNAH2 | c.2638del p.X880_splice | Splice Site (DEL) | VAF 22/114 reads (19%) | called by mutect2, pindel, varscan2
- DNMT3A | c.1717dup p.Q573Pfs*5 | Frame Shift Ins (INS) | VAF 50/94 reads (53%) | called by mutect2, pindel, varscan2
- EPHX2 | c.1287del p.F429Lfs*2 | Frame Shift Del (DEL) | VAF 45/151 reads (30%) | called by mutect2, pindel, varscan2
- OR6C1 | c.253del p.S85Qfs*12 | Frame Shift Del (DEL) | VAF 42/93 reads (45%) | called by mutect2, pindel, varscan2
- P4HA3 | c.647dup p.E217Rfs*7 | Frame Shift Ins (INS) | VAF 24/76 reads (32%) | called by mutect2, pindel, varscan2
- PLLP | c.310-1del p.X104_splice | Splice Site (DEL) | VAF 17/95 reads (18%) | called by mutect2, pindel, varscan2
- PLVAP | c.1226del p.N409Tfs*29 | Frame Shift Del (DEL) | VAF 29/111 reads (26%) | called by mutect2, pindel, varscan2
- SPTBN1 | c.388_398del p.L130Gfs*4 | Frame Shift Del (DEL) | VAF 83/125 reads (66%) | called by mutect2, pindel, varscan2
- SUGP2 | c.3032del p.D1011Vfs*61 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- TMEM50B | c.62_63del p.R21Kfs*22 | Frame Shift Del (DEL) | VAF 26/107 reads (24%) | called by pindel, varscan2
- VDAC3 | c.837del p.F279Lfs*9 | Frame Shift Del (DEL) | VAF 39/148 reads (26%) | called by mutect2, pindel, varscan2
- ARSB | c.1158C>T p.S386= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV99365469; called by muse, mutect2, varscan2
- C2CD5 | c.2475A>G p.Q825= | Silent (SNP) | VAF 34/153 reads (22%) | catalogued as COSV100448981; called by muse, mutect2, varscan2
- CANX | c.1443G>A p.P481= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs775928635, COSV56002799; called by muse, mutect2, varscan2
- FLYWCH1 | c.546G>A p.E182= (on ENST00000253928 / NM_001308068.2; = p.E181= on NM_020912.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs1329591996, COSV99559193; called by muse, mutect2, varscan2
- FOXI1 | c.24G>T p.A8= | Silent (SNP) | VAF 64/201 reads (32%) | catalogued as COSV100089549, COSV60388306; called by muse, mutect2, varscan2
- GPATCH1 | c.1398C>T p.A466= | Silent (SNP) | VAF 78/211 reads (37%) | catalogued as COSV99404292; called by muse, mutect2, varscan2
- GPR89A | c.111G>A p.Q37= | Silent (SNP) | VAF 124/478 reads (26%) | catalogued as COSV100572520; called by muse, mutect2, varscan2
- GRIA1 | c.1893A>G p.T631= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as COSV99601928; called by muse, mutect2, varscan2
- HIVEP1 | c.3327G>A p.S1109= | Silent (SNP) | VAF 87/268 reads (32%) | catalogued as rs201766884, COSV101045648; called by muse, mutect2, varscan2
- HYDIN | c.1194G>C p.L398= | Silent (SNP) | VAF 45/93 reads (48%) | catalogued as COSV99864886; called by muse, mutect2
- KCND2 | c.753G>T p.A251= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV58572523, COSV58572595; called by muse, mutect2, varscan2
- KRT13 | c.1329C>A p.T443= | Silent (SNP) | VAF 25/185 reads (14%) | catalogued as COSV99877488; called by muse, mutect2, varscan2
- NHLRC1 | c.6G>T p.A2= | Silent (SNP) | VAF 66/180 reads (37%) | catalogued as rs1473552563, COSV100513547; called by muse, mutect2, varscan2
- NUP42 | c.6C>T p.A2= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99331149; called by muse, mutect2, varscan2
- PDCD6IP | c.1827A>G p.G609= | Silent (SNP) | VAF 124/415 reads (30%) | catalogued as COSV100219116; called by muse, varscan2
- PHLDB1 | c.1407C>T p.L469= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV100616743; called by muse, mutect2
- PRELP | c.438G>T p.L146= | Silent (SNP) | VAF 56/157 reads (36%) | catalogued as COSV100557939; called by muse, mutect2, varscan2
- RWDD2B | c.852T>A p.V284= | Silent (SNP) | VAF 49/112 reads (44%) | catalogued as COSV99725715; called by muse, mutect2, varscan2
- SIN3B | c.1467C>T p.D489= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as rs761987982, COSV56131034; called by muse, mutect2, varscan2
- SPPL2B | c.972C>A p.L324= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV101194683; called by muse, mutect2, varscan2
- TBC1D32 | c.2928G>T p.V976= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as COSV99251072; called by muse, mutect2, varscan2
- TMEM132E | c.2040T>C p.P680= (on ENST00000321639; = p.P770= on NM_001304438.2) | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV100396714; called by muse, mutect2, varscan2
- ZNF709 | c.1230T>C p.H410= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as COSV101172273; called by muse, mutect2, varscan2
